CCDI case PBCJLM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/89bf6606-7516-411e-a7be-7c11b1537555

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.6 years (587 days).

Biospecimens (3 samples)
- Sample 0DTD33: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTD37: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTD3B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
